FM case AD11657 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/e91029ea-b455-4507-ae61-ce30057b08af

Female, 75.4 years: Adenoid cystic carcinoma (ICD-O-3 8200/3); specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
